Somatic mutation profile of tumor specimen PCProject_0120_T2_WES (aliquot PCProject_0120_T2_WES_1) from CMI case PCProject_0120, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.5 years (23,202 days).
Specimen PCProject_0120_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c92350e-b33a-4e89-9a92-251a8113698c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0120_SALIVA (DNA), aliquot PCProject_0120_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f3c2bbd-9c13-4c2a-b5d0-181d25be973e

The open-access MAF lists 32 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, In Frame Del 3, Intron 2, 5'Flank 2, 3'UTR 2, Frame Shift Del 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.391T>G p.W131G | Missense Mutation (SNP) | VAF 43/113 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as rs1057519968, COSV61652911, COSV61653817; ClinVar: likely pathogenic; called by muse, varscan2
- CA10 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99563881; called by muse, mutect2, varscan2
- KLHL28 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1041605403, COSV61888155; called by muse, mutect2
- SNAI2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 36/425 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.024); catalogued as COSV50078589; called by muse, mutect2
- ZBED8 | c.1391T>C p.I464T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs199786578; called by muse, mutect2, varscan2
- AC100868.1 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- ADGRV1 | c.15195del p.Q5066Kfs*11 | Frame Shift Del (DEL) | VAF 28/134 reads (21%) | called by mutect2, pindel, varscan2
- ASXL3 | c.3589G>T p.D1197Y | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- C9orf72 | c.1289_1306del p.L430_D436delinsH | In Frame Del (DEL) | VAF 39/145 reads (27%) | called by mutect2, pindel
- CALHM1 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, varscan2
- CRAMP1 | c.2266T>G p.S756A | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- DAG1 | c.2402C>T p.A801V | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- EXOC6B | c.1430T>G p.I477R | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FBLN1 | c.438G>C p.K146N | Missense Mutation (SNP) | VAF 95/303 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- FHOD1 | c.2984T>C p.L995P | Missense Mutation (SNP) | VAF 85/266 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GALNT13 | c.1006_1008del p.V336del | In Frame Del (DEL) | VAF 26/89 reads (29%) | called by mutect2, pindel, varscan2
- KANSL1L | c.262A>G p.T88A | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KLHL30 | c.1259G>T p.C420F | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- MAP4K1 | c.975_983del p.S325_G328delinsR | In Frame Del (DEL) | VAF 34/98 reads (35%) | called by mutect2, pindel, varscan2
- RBFOX1 | c.404C>A p.T135N (on ENST00000641259; = p.T19N on NM_001308117.1) | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- MYO1A | c.645C>T p.A215= | Silent (SNP) | VAF 14/247 reads (6%) | called by muse, mutect2
- OR13J1 | c.660C>A p.L220= | Silent (SNP) | VAF 58/188 reads (31%) | called by muse, mutect2, varscan2
- PPP3CA | c.921A>G p.S307= | Silent (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- ROBO2 | c.517C>A p.R173= | Silent (SNP) | VAF 63/208 reads (30%) | catalogued as COSV59902199; called by muse, varscan2
- TMEM132D | c.1743G>A p.T581= | Silent (SNP) | VAF 64/233 reads (27%) | catalogued as rs773542582, COSV67160273; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | chr3:51975071 C>A | 5'Flank (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- AL035696.1 | n.182C>A | RNA (SNP) | VAF 56/151 reads (37%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.*2del | 3'UTR (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- CTDP1 | chr18:79679422 C>T | 5'Flank (SNP) | VAF 48/141 reads (34%) | catalogued as rs1176070506; called by muse, mutect2, varscan2
- CYB5RL | c.541-793T>C | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as rs1214098470; called by muse, varscan2
- FOXA1 | c.*27_*28insCT | 3'UTR (INS) | VAF 142/552 reads (26%) | called by mutect2, pindel, varscan2
- TLCD3B | c.125+343G>T | Intron (SNP) | VAF 64/232 reads (28%) | called by muse, varscan2
